Somatic mutation profile of tumor specimen 0DU090 from CCDI case PBCJIG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,441 days).
Specimen 0DU090: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91dd3227-9c2a-4cf9-9a29-0fe7c4e48f8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dcfce18-a7fd-4f00-a281-e04b8e695754

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 4, Silent 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 203/729 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAM30 | c.2219T>G p.V740G | Missense Mutation (SNP) | VAF 223/893 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs61757468, COSV65560640; called by muse, mutect2, varscan2
- CCDC89 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 158/615 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs777244675, COSV100320857; called by muse, mutect2, varscan2
- CELSR3 | c.9244C>T p.R3082C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as rs760477755; called by muse, mutect2
- FAM193B | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364030761; called by muse, mutect2, varscan2
- SPATA48 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 120/790 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs773612283; called by muse, mutect2, varscan2
- TLR3 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 195/893 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1437341922; called by muse, mutect2, varscan2
- CRYBG3 | c.7135C>T p.L2379F | Missense Mutation (SNP) | VAF 155/679 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CTNNA2 | c.2440C>T p.Q814* | Nonsense Mutation (SNP) | VAF 34/984 reads (3%) | called by muse, mutect2
- GSDME | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NOTCH2 | c.1085G>C p.C362S | Missense Mutation (SNP) | VAF 115/584 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- NOTCH2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 168/624 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRIM2 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 89/997 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2
- PTPRQ | c.6103A>C p.K2035Q (on ENST00000616559; = p.K2002Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 46/1172 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- ABCA3 | c.1836G>A p.P612= | Silent (SNP) | VAF 73/267 reads (27%) | catalogued as rs768542119, COSV57053413; called by muse, mutect2, varscan2
- PCED1B | c.684C>T p.D228= | Silent (SNP) | VAF 53/220 reads (24%) | called by muse, mutect2, varscan2
- ARMH1 | c.1128+89C>T | Intron (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- DOCK5 | c.1443+40C>T | Intron (SNP) | VAF 30/206 reads (15%) | catalogued as rs754200963; called by muse, mutect2, varscan2
- MLLT6 | c.1037-74G>A | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs950946618; called by muse, mutect2, varscan2
- POLR3H | c.*2040C>T | 3'UTR (SNP) | VAF 17/59 reads (29%) | catalogued as rs113229682; called by muse, mutect2, varscan2
- SF3B2 | c.134-39G>C | Intron (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
